Somatic mutation profile of tumor specimen C3L-00814-01 (aliquot CPT0065810009) from CPTAC case C3L-00814, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 83.9 years (30,635 days).
Specimen C3L-00814-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6d5da60-f0bb-4dcd-acac-1b2c6c054893.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00814-31 (Blood Derived Normal), aliquot CPT0067690002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb979d06-a929-4eca-9376-d6c9226414d6

The open-access MAF lists 59 somatic variants for this specimen: 48 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Frame Shift Del 10, Silent 5, Nonsense Mutation 4, Intron 4, In Frame Del 2, Splice Site 1, 5'Flank 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.214T>C p.S72P | Missense Mutation (SNP) | VAF 96/273 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); catalogued as rs869025618, CD962175, CM071138, COSV56544742, COSV56567680; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRB2 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as COSV57072489; called by muse, mutect2, varscan2
- ADH7 | c.641G>C p.G214A | Missense Mutation (SNP) | VAF 9/211 reads (4%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.741); catalogued as COSV52921999; called by muse, mutect2
- CHST4 | c.1083C>G p.H361Q | Missense Mutation (SNP) | VAF 56/297 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100632765; called by muse, mutect2, varscan2
- DNAJC13 | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 35/210 reads (17%) | catalogued as rs751081895; called by muse, mutect2, varscan2
- DUSP22 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 22/498 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1312196747; called by muse, mutect2
- FHOD1 | c.974C>T p.T325M | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs1162115126, COSV50759762; called by muse, mutect2
- L3MBTL1 | c.1666A>G p.I556V (on ENST00000418998 / NM_001377303.1; = p.I466V on NM_015478.7) | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as rs772712126; called by muse, mutect2, varscan2
- MUC17 | c.7775G>A p.S2592N | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs763523521, COSV60282270; called by muse, mutect2, varscan2
- NF1 | c.5490del p.W1831Gfs*32 (on ENST00000358273 / NM_001042492.3; = p.W1810Gfs*32 on NM_000267.3) | Frame Shift Del (DEL) | VAF 47/157 reads (30%) | catalogued as COSV62197710; called by mutect2, pindel, varscan2
- SLC9A3 | c.2084C>A p.P695H | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99376427; called by muse, mutect2, varscan2
- SREK1IP1 | c.261del p.R91Gfs*67 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as COSV72486171; called by pindel, varscan2
- UBASH3B | c.1123G>T p.V375F | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as rs756250615; called by muse, mutect2, varscan2
- ZACN | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 90/312 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs566441531, COSV58036121; called by muse, mutect2, varscan2
- ZNF317 | c.1592A>G p.E531G | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56111625; called by muse, mutect2, varscan2
- ACSL1 | c.818T>G p.I273S | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- ANKRD6 | c.335T>G p.L112W | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP9 | c.-78G>C | Splice Region (SNP) | VAF 70/230 reads (30%) | called by muse, mutect2, varscan2
- BOP1 | c.551C>A p.T184N | Missense Mutation (SNP) | VAF 218/743 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CFAP221 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CNGA1 | c.1810_1827del p.L604_I609del | In Frame Del (DEL) | VAF 110/504 reads (22%) | called by mutect2, pindel, varscan2
- CSKMT | c.589_595del p.F197Mfs*20 | Frame Shift Del (DEL) | VAF 52/236 reads (22%) | called by mutect2, pindel, varscan2
- DBT | c.772+1G>T p.X258_splice | Splice Site (SNP) | VAF 88/386 reads (23%) | called by mutect2, varscan2
- DNAH3 | c.9301C>A p.L3101M | Missense Mutation (SNP) | VAF 91/472 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EXOSC8 | c.683A>T p.E228V | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- GNE | c.1115A>T p.D372V (on ENST00000396594 / NM_001128227.3; = p.D341V on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/583 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.069); called by muse, mutect2
- GPR179 | c.6493G>A p.G2165R (on ENST00000621958; = p.G2164R on NM_001004334.4) | Missense Mutation (SNP) | VAF 100/354 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MEGF6 | c.1777_1780del p.N593Vfs*117 | Frame Shift Del (DEL) | VAF 60/260 reads (23%) | called by pindel, varscan2
- MSH2 | c.329A>T p.K110M | Missense Mutation (SNP) | VAF 89/364 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NDRG1 | c.1096_1113del p.T366_H371del | In Frame Del (DEL) | VAF 28/123 reads (23%) | called by mutect2, pindel, varscan2
- NLRP6 | c.850C>G p.L284V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- NOL10 | c.1569_1570del p.L524Rfs*7 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | called by pindel, varscan2
- OR10X1 | c.380del p.N127Tfs*7 | Frame Shift Del (DEL) | VAF 54/186 reads (29%) | called by mutect2, pindel, varscan2
- OR1C1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OTOP2 | c.959_960del p.R320Hfs*33 | Frame Shift Del (DEL) | VAF 58/198 reads (29%) | called by mutect2, pindel, varscan2
- PBRM1 | c.3771T>A p.C1257* (on ENST00000296302 / NM_001366071.2; = p.C1232* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 60/163 reads (37%) | called by muse, mutect2, varscan2
- PJA2 | c.770_773del p.Q257Rfs*56 | Frame Shift Del (DEL) | VAF 67/180 reads (37%) | called by mutect2, pindel, varscan2
- RORB | c.856G>T p.E286* (on ENST00000396204 / NM_001365023.1; = p.E275* on NM_006914.4) | Nonsense Mutation (SNP) | VAF 20/292 reads (7%) | called by muse, mutect2
- SLC25A47 | c.744C>G p.D248E | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLITRK6 | c.1418T>A p.V473D | Missense Mutation (SNP) | VAF 77/241 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- TMEM86A | c.80T>C p.V27A | Missense Mutation (SNP) | VAF 19/346 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- TMPRSS13 | c.738del p.W246Cfs*44 | Frame Shift Del (DEL) | VAF 43/195 reads (22%) | called by mutect2, pindel, varscan2
- TTC37 | c.630G>C p.Q210H | Missense Mutation (SNP) | VAF 68/243 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- VIT | c.1123G>A p.A375T (on ENST00000389975 / NM_001177969.1; = p.A390T on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- VPS50 | c.2044del p.S682Afs*5 | Frame Shift Del (DEL) | VAF 30/161 reads (19%) | called by mutect2, pindel, varscan2
- VWA3B | c.2809G>T p.V937F | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- WDR87 | c.3698G>A p.R1233K | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- ZNF852 | c.1488G>T p.M496I | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- CPNE9 | c.1203G>A p.G401= | Silent (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- DNAH12 | c.3261C>T p.A1087= (on ENST00000351747; = p.A1110= on NM_001366028.2) | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, varscan2
- NEUROG1 | c.681C>T p.L227= | Silent (SNP) | VAF 53/184 reads (29%) | catalogued as COSV59083088; called by muse, mutect2, varscan2
- RTN1 | c.1593G>A p.Q531= | Silent (SNP) | VAF 68/246 reads (28%) | catalogued as rs746269097, COSV50731625; called by muse, mutect2, varscan2
- ZNF420 | c.1797C>T p.G599= | Silent (SNP) | VAF 77/237 reads (32%) | called by muse, mutect2, varscan2
- ALMS1P1 | n.1043-9647A>G | Intron (SNP) | VAF 26/140 reads (19%) | called by muse, mutect2, varscan2
- CCR7 | c.-22del | 5'UTR (DEL) | VAF 55/250 reads (22%) | called by mutect2, pindel, varscan2
- DHX30 | c.125-2270G>A | Intron (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- GPC1 | c.167-6096G>A | Intron (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- PIEZO1 | c.161-738G>C | Intron (SNP) | VAF 13/96 reads (14%) | catalogued as rs1222597391, COSV99966376; called by muse, mutect2, varscan2
- RFK | chr9:76399123 T>C | 5'Flank (SNP) | VAF 48/724 reads (7%) | called by muse, mutect2
